Somatic mutation profile of tumor specimen TCGA-D8-A1XO-01A (aliquot TCGA-D8-A1XO-01A-11D-A14K-09) from TCGA case TCGA-D8-A1XO, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 56.4 years (20,606 days).
Specimen TCGA-D8-A1XO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a842bd1d-5665-4ccf-a409-0de1e19e0f82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1XO-10A (Blood Derived Normal), aliquot TCGA-D8-A1XO-10A-01D-A14K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bd53535-21f4-4ac5-a2bd-ce5e77a9c602

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, Nonsense Mutation 4, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 9/16 reads (56%) | hotspot (GDC flag); catalogued as COSV55726950; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 30/83 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FAT2 | c.6460C>T p.Q2154* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV55812282; called by muse, mutect2, varscan2
- FKBP8 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV55890924; called by muse, mutect2, varscan2
- ITGB3BP | c.401G>C p.R134T | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as COSV52129854; called by muse, mutect2, varscan2
- KCNMA1 | c.796A>T p.R266* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV54224285; called by muse, mutect2, varscan2
- KMT2E | c.1183G>T p.V395F | Missense Mutation (SNP) | VAF 71/223 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57568968; called by muse, mutect2, varscan2
- POPDC3 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs143330551; called by muse, mutect2, varscan2
- RNF215 | c.1067T>A p.L356Q | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53175171; called by muse, mutect2, varscan2
- STK31 | c.1045A>G p.T349A | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.031); catalogued as COSV63453705; called by muse, mutect2, varscan2
- VGLL3 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.058); catalogued as rs1388532002, COSV101051877, COSV101051922; called by muse, mutect2, varscan2
- ZFHX3 | c.4168C>T p.Q1390* | Nonsense Mutation (SNP) | VAF 53/97 reads (55%) | catalogued as COSV51706416; called by muse, mutect2, varscan2
- AR | c.93C>T p.R31= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV65952462; called by muse, mutect2, varscan2
- ATM | c.1296G>T p.L432= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV53723528; called by muse, mutect2
- MCL1 | c.648T>A p.V216= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100329515, COSV57189591; called by muse, mutect2, varscan2
- NPHS1 | c.3579C>T p.Y1193= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs747950877, COSV62286104; called by muse, mutect2, varscan2
- PPM1B | c.714C>T p.I238= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as COSV56764657; called by muse, mutect2, varscan2
- NXF5 | n.525C>T | RNA (SNP) | VAF 48/190 reads (25%) | catalogued as COSV53789439; called by muse, mutect2, varscan2
